Somatic mutation profile of tumor specimen TCGA-13-0886-01A (aliquot TCGA-13-0886-01A-01W-0420-08) from TCGA case TCGA-13-0886, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.7 years (24,724 days).
Specimen TCGA-13-0886-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a529f44-15b0-49c4-86a8-bb8a7013b400.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0886-10A (Blood Derived Normal), aliquot TCGA-13-0886-10A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/849cade0-effb-40da-a451-45cf18dcb029

The open-access MAF lists 115 somatic variants for this specimen: 89 protein-altering or splice-affecting, 26 silent.
By variant classification: Missense Mutation 70, Silent 26, Frame Shift Del 9, Frame Shift Ins 5, Nonsense Mutation 2, Splice Site 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMPRSS6 | c.1786dup p.A596Gfs*5 | Frame Shift Ins (INS) | VAF 12/69 reads (17%) | catalogued as rs767094129; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 126/343 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABR | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV56838784; called by muse, mutect2, varscan2
- AHCTF1 | c.3649G>T p.A1217S (on ENST00000366508; = p.A1191S on NM_015446.5) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58251967; called by muse, mutect2, varscan2
- ALDH3A1 | c.782T>G p.V261G | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56735854; called by muse, mutect2, varscan2
- ASCC3 | c.5278T>C p.F1760L | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100976159; called by muse, mutect2
- COL16A1 | c.254C>A p.T85N | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV54709262; called by muse, mutect2, varscan2
- CRPPA | c.305T>G p.M102R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.736); catalogued as COSV67907100; called by muse, mutect2, varscan2
- CRYBB1 | c.447C>A p.H149Q | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53233824; called by muse, mutect2, varscan2
- DCD | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.701); catalogued as COSV53201910; called by muse, mutect2, varscan2
- DCUN1D3 | c.562C>A p.Q188K | Missense Mutation (SNP) | VAF 81/311 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.042); catalogued as COSV60953921; called by muse, mutect2, varscan2
- DDX6 | c.1099A>G p.K367E | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as COSV50589929; called by muse, mutect2
- DSCAM | c.2617G>T p.E873* | Nonsense Mutation (SNP) | VAF 49/241 reads (20%) | catalogued as COSV101261990, COSV68030053; called by muse, mutect2, varscan2
- DST | c.3065A>G p.D1022G (on ENST00000361203 / NM_001374722.1; = p.D696G on NM_001723.6) | Missense Mutation (SNP) | VAF 85/315 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV55023724; called by muse, mutect2, varscan2
- DST | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 56/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56829153; called by muse, mutect2
- EGF | c.1448C>A p.P483Q | Missense Mutation (SNP) | VAF 153/528 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1384197102, COSV99490348; called by muse, mutect2, varscan2
- EPHB1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV67664609; called by muse, mutect2, varscan2
- FAT1 | c.6799G>T p.V2267L | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71674870; called by muse, mutect2, varscan2
- FBXO16 | c.443A>T p.E148V | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60776616; called by muse, mutect2, varscan2
- GBX2 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100103631, COSV60445560; called by muse, mutect2
- GMCL1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV57002393; called by muse, mutect2, varscan2
- GZMA | c.157A>T p.I53F | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV57113686, COSV57114357; called by muse, mutect2, varscan2
- HUWE1 | c.4918T>A p.S1640T | Missense Mutation (SNP) | VAF 109/456 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV53352675; called by muse, mutect2, varscan2
- IGSF1 | c.3284C>T p.T1095I | Missense Mutation (SNP) | VAF 118/1619 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs1224417790, COSV100811764; called by muse, mutect2
- L3MBTL3 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.445); catalogued as COSV62387011; called by muse, mutect2, varscan2
- LRRC8C | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs749404793, COSV64999276, COSV65000461; called by muse, mutect2, varscan2
- LY96 | c.377T>A p.F126Y | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV99514230; called by muse, mutect2, varscan2
- MTUS2 | c.2963C>A p.P988Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as COSV101462161, COSV70917878; called by muse, mutect2, varscan2
- MYOCD | c.684dup p.S229Qfs*17 | Frame Shift Ins (INS) | VAF 14/97 reads (14%) | catalogued as rs760792013; called by mutect2, varscan2
- NEK8 | c.1239G>T p.M413I | Missense Mutation (SNP) | VAF 15/267 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV99261406; called by muse, mutect2
- NID1 | c.945C>A p.Y315* | Nonsense Mutation (SNP) | VAF 12/322 reads (4%) | catalogued as COSV99937922; called by muse, mutect2
- NLRP14 | c.1193C>A p.A398D | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as rs1207501906, COSV55068899; called by muse, mutect2, varscan2
- OCRL | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100843298; called by muse, mutect2
- OR4B1 | c.671G>C p.R224T | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58883250; called by muse, mutect2, varscan2
- OR51G1 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs754142789, COSV58969730; called by muse, mutect2, varscan2
- OR5M10 | c.104A>C p.Y35S | Missense Mutation (SNP) | VAF 88/311 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV73242362; called by muse, varscan2
- PLB1 | c.2669G>T p.R890I | Missense Mutation (SNP) | VAF 403/928 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV59829313, COSV99065371; called by muse, mutect2, varscan2
- RSAD2 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101149980, COSV65908510; called by muse, mutect2, varscan2
- RYR2 | c.14621G>C p.R4874T | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV100767262; called by muse, mutect2
- SACS | c.5225G>A p.C1742Y | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as COSV101207129; called by muse, mutect2
- SCEL | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV62993915; called by muse, mutect2, varscan2
- SHOX2 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV99905236; called by mutect2, varscan2
- SIPA1L3 | c.4181dup p.S1395Qfs*10 | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | catalogued as rs758776420; called by mutect2, pindel
- SLC17A1 | c.64T>A p.L22M | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.701); catalogued as COSV55080004; called by muse, mutect2, varscan2
- SLC6A19 | c.1724A>G p.K575R | Missense Mutation (SNP) | VAF 10/289 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs979189302; called by muse, mutect2
- SMOC1 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV62762066; called by muse, mutect2, varscan2
- SPATA32 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 113/314 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.453); catalogued as COSV59304137; called by muse, mutect2, varscan2
- SYNJ2 | c.3103G>C p.E1035Q | Missense Mutation (SNP) | VAF 210/1216 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as COSV100839983; called by muse, mutect2, varscan2
- TAF6L | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs750187135, COSV53669619; called by muse, mutect2, varscan2
- TARS2 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 313/1305 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64695977; called by muse, mutect2, varscan2
- TBC1D3B | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1193421897; called by muse, mutect2, varscan2
- TKTL1 | c.1472C>G p.A491G | Missense Mutation (SNP) | VAF 171/692 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as COSV54213646; called by muse, mutect2, varscan2
- TTBK1 | c.1571G>A p.S524N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV52493330; called by muse, mutect2, varscan2
- TTLL4 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV51437327; called by muse, mutect2, varscan2
- TUBB1 | c.502A>T p.S168C | Missense Mutation (SNP) | VAF 99/246 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53887249; called by muse, mutect2, varscan2
- UNC5CL | c.97T>C p.W33R | Missense Mutation (SNP) | VAF 91/342 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as rs776689093, COSV55110730; called by muse, mutect2, varscan2
- USF1 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 89/254 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV57038695; called by muse, mutect2, varscan2
- WHRN | c.1267C>G p.R423G | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as CM140300, COSV54332256; called by muse, mutect2, varscan2
- YLPM1 | c.3137G>A p.S1046N | Missense Mutation (SNP) | VAF 151/409 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV53115193; called by muse, mutect2, varscan2
- ZBED9 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV71729548; called by muse, mutect2, varscan2
- ZNF513 | c.1147A>T p.S383C | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV52008679; called by muse, mutect2, varscan2
- ABCB1 | c.3805T>A p.S1269T | Missense Mutation (SNP) | VAF 30/537 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- ABRA | c.224C>A p.A75D | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- ASPRV1 | c.28_38del p.I10Sfs*4 | Frame Shift Del (DEL) | VAF 51/266 reads (19%) | called by mutect2, pindel, varscan2
- BPTF | c.2010G>A p.M670I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2
- CAPNS1 | c.706C>A p.L236M | Missense Mutation (SNP) | VAF 76/394 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CD1B | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 331/1271 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP61 | c.1872del p.I624Mfs*10 | Frame Shift Del (DEL) | VAF 37/288 reads (13%) | called by mutect2, pindel, varscan2
- DDX21 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- ELSPBP1 | c.144C>G p.S48R | Missense Mutation (SNP) | VAF 51/666 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.766); called by muse, mutect2
- FBXO3 | c.1296_1300del p.E433Rfs*3 | Frame Shift Del (DEL) | VAF 109/564 reads (19%) | called by mutect2, pindel, varscan2
- HSPG2 | c.11192dup p.R3732Kfs*44 | Frame Shift Ins (INS) | VAF 12/138 reads (9%) | called by mutect2, pindel
- IGHV3-35 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 71/1240 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.296); called by muse, mutect2
- ITGA10 | c.2439_2442del p.P814Lfs*28 | Frame Shift Del (DEL) | VAF 351/1441 reads (24%) | called by mutect2, pindel, varscan2
- LY6G6C | c.88G>C p.V30L | Missense Mutation (SNP) | VAF 15/571 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- NR1H4 | c.128T>A p.V43E (on ENST00000551379 / NM_001206993.2; = p.V33E on NM_005123.4) | Missense Mutation (SNP) | VAF 80/1018 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- PLEKHO2 | c.92del p.G31Afs*99 | Frame Shift Del (DEL) | VAF 49/266 reads (18%) | called by mutect2, pindel, varscan2
- PLK3 | c.436-1G>A p.X146_splice | Splice Site (SNP) | VAF 33/81 reads (41%) | called by mutect2, varscan2
- PLVAP | c.835A>C p.M279L | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.66); called by muse, mutect2
- PPM1K | c.731del p.V244Efs*11 | Frame Shift Del (DEL) | VAF 63/474 reads (13%) | called by mutect2, varscan2
- SLC44A4 | c.1746G>T p.M582I | Missense Mutation (SNP) | VAF 132/994 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, varscan2
- TOX2 | c.1228dup p.Q410Pfs*32 (on ENST00000358131 / NM_001098798.2; = p.Q386Pfs*32 on NM_032883.3) | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by pindel, varscan2
- TSC2 | c.2394_2409del p.R799Afs*25 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- TSLP | c.4T>A p.F2I | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.087); called by muse, mutect2
- TTLL4 | c.776_796del p.G259_P265del | In Frame Del (DEL) | VAF 73/399 reads (18%) | called by mutect2, pindel, varscan2
- UBXN7 | c.995_996delinsA p.V332Dfs*10 | Frame Shift Del (DEL) | VAF 44/289 reads (15%) | called by pindel, varscan2*
- VPS13B | c.3938_3941del p.S1313Ifs*22 | Frame Shift Del (DEL) | VAF 79/356 reads (22%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.9239A>C p.Q3080P | Missense Mutation (SNP) | VAF 14/466 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.213); called by muse, mutect2
- ZFHX4 | c.9240G>T p.Q3080H | Missense Mutation (SNP) | VAF 14/466 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ADAM19 | c.2157G>T p.L719= | Silent (SNP) | VAF 260/1094 reads (24%) | catalogued as COSV57433216; called by muse, mutect2, varscan2
- BIN1 | c.843C>G p.V281= (on ENST00000316724 / NM_001320642.1; = p.V250= on NM_004305.4) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV52119788; called by muse, mutect2, varscan2
- CGNL1 | c.2622A>T p.R874= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV55570664; called by muse, mutect2, varscan2
- CPA2 | c.1194C>G p.P398= | Silent (SNP) | VAF 70/294 reads (24%) | catalogued as COSV55980341; called by muse, mutect2, varscan2
- CYP11B2 | c.1005C>T p.D335= | Silent (SNP) | VAF 106/413 reads (26%) | catalogued as rs534512378, COSV59995214; called by muse, mutect2, varscan2
- EIF3M | c.57T>G p.R19= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV60073088; called by muse, mutect2, varscan2
- GPBP1L1 | c.378C>T p.S126= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs756642493, COSV51970699, COSV99321985; called by muse, mutect2, varscan2
- GPR15 | c.135G>A p.L45= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV99423679; called by muse, mutect2
- KIAA1522 | c.1281C>A p.G427= (on ENST00000373480 / NM_001198972.2; = p.G486= on NM_020888.3) | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV53865685; called by muse, mutect2, varscan2
- KRT83 | c.1149C>G p.A383= | Silent (SNP) | VAF 17/493 reads (3%) | catalogued as COSV99531265; called by muse, mutect2
- LAMB3 | c.1680C>T p.T560= | Silent (SNP) | VAF 10/137 reads (7%) | catalogued as rs376183751, COSV61919632; ClinVar: likely benign; called by muse, mutect2
- NDFIP2 | c.408G>A p.A136= | Silent (SNP) | VAF 138/467 reads (30%) | catalogued as rs371388745; called by muse, mutect2, varscan2
- PCDH1 | c.714G>A p.L238= | Silent (SNP) | VAF 51/210 reads (24%) | catalogued as COSV54616016; called by muse, mutect2, varscan2
- PCDHGA3 | c.2190C>T p.G730= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs376373404; called by muse, mutect2, varscan2
- PF4V1 | c.15C>G p.A5= | Silent (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- RGL3 | c.1836G>A p.S612= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs376798441; called by muse, mutect2, varscan2
- SIMC1 | c.1752C>G p.T584= (on ENST00000443967 / NM_001308196.1; = p.T169= on NM_198567.5) | Silent (SNP) | VAF 67/304 reads (22%) | catalogued as rs772679526, COSV57904591; called by muse, mutect2, varscan2
- SLC26A11 | c.1569C>T p.S523= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs1450623722, COSV63280011; called by muse, mutect2, varscan2
- STK10 | c.1539C>A p.G513= | Silent (SNP) | VAF 69/537 reads (13%) | catalogued as COSV51575864; called by muse, mutect2, varscan2
- TBX5 | c.1116G>A p.S372= | Silent (SNP) | VAF 137/514 reads (27%) | catalogued as rs763827720, COSV59859102, COSV59862719; ClinVar: uncertain significance; called by muse, varscan2
- THSD1 | c.2019G>A p.L673= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV51629753; called by muse, mutect2, varscan2
- TNFRSF8 | c.366T>C p.C122= | Silent (SNP) | VAF 192/515 reads (37%) | catalogued as COSV55797879; called by muse, mutect2, varscan2
- TRRAP | c.2322C>A p.L774= | Silent (SNP) | VAF 86/396 reads (22%) | catalogued as COSV62847887; called by muse, mutect2, varscan2
- TTLL4 | c.3024G>T p.R1008= | Silent (SNP) | VAF 98/398 reads (25%) | catalogued as COSV51437340; called by muse, mutect2, varscan2
- UBE2O | c.1290C>T p.A430= | Silent (SNP) | VAF 12/312 reads (4%) | catalogued as COSV100084004; called by muse, mutect2
- ZNF471 | c.1620G>A p.E540= | Silent (SNP) | VAF 55/117 reads (47%) | catalogued as COSV57292131; called by muse, mutect2, varscan2
